Gene-level copy-number profile of tumor specimen C3L-01246-01 from CPTAC case C3L-01246, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.8 years (22,948 days).
Specimen C3L-01246-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file deff43f6-ab24-4624-99e7-ff6873b8013b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01246-72 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/7030a891-409e-445f-99d8-a6482e6d4356

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 14,929; copy number 2: 25,743; copy number 3: 13,806; copy number 4: 3,495; copy number 5: 140; copy number 6: 97; copy number 7: 13; copy number 9: 151.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–157,887, 7 genes (within-gene range 0–4): AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr1:143,498,785–143,500,512, 2 genes: AC239859.2, LINC02799.
- chr12:28,319,335–28,319,463, 1 gene (within-gene range 0–1): RNU4-54P.
- chr21:44,172,169–44,194,338, 2 genes: AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 401 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–594,768, 10 genes, copy number 7: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1.
- chr3:13,479,724–13,746,638, 3 genes, copy number 5 (within-gene range 4–5): HDAC11, FBLN2, LINC00620.
- chr3:188,941,715–198,123,232, 209 genes, copy number 5–6 (broad region; genes not listed).
- chr4:40,743,627–41,303,337, 12 genes, copy number 5: AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA.
- chr8:145,047,860–145,066,685, 2 genes, copy number 5: AC139103.1, C8orf33.
- chr19:37,401,404–40,690,972, 165 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
